TCGA case TCGA-NQ-A638 — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5a197d56-e835-4f96-ad85-04ae9f6aff32

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Mesothelioma, malignant: ICD-O-3 morphology code: 9050/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 66.8 years (24,410 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: -8 days.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.

Follow-up (1 entry)
- Days to follow up: -8 days; Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-NQ-A638-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 70 mg.
  Slide TCGA-NQ-A638-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-NQ-A638-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-NQ-A638-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma.
- Follow-up form: Lost to follow-up: Yes; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 0 days; disease-specific survival: no event (censored), 0 days; disease-free interval: no event (censored), 0 days; progression-free interval: no event (censored), 0 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-NQ-A638-01A-11D-A34B-01): tumor purity 0.61, ploidy 2.84, whole-genome doublings 1.
